Somatic mutation profile of tumor specimen TCGA-B5-A1MS-01B (aliquot TCGA-B5-A1MS-01B-11D-A228-09) from TCGA case TCGA-B5-A1MS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 60.4 years (22,068 days).
Specimen TCGA-B5-A1MS-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b07fb207-a3f0-400f-8705-a0f43945deab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A1MS-10A (Blood Derived Normal), aliquot TCGA-B5-A1MS-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7563cb5-8fbe-417c-9cbc-215c16302206

The open-access MAF lists 49 somatic variants for this specimen: 40 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, Nonsense Mutation 3, Frame Shift Del 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 229/271 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- TP53 | c.920-5_920delinsT p.X307_splice | Splice Site (DEL) | VAF 25/99 reads (25%) | hotspot (GDC flag); called by pindel, varscan2*
- TP53 | c.660T>A p.Y220* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | hotspot (GDC flag); catalogued as rs1567551150, CD101595, COSV52775381, COSV52839743, COSV53289049; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.2183G>T p.G728V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899465; called by muse, mutect2, varscan2
- AGTR1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100837048; called by muse, mutect2, varscan2
- BPIFB3 | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100972355; called by muse, mutect2, varscan2
- C1orf226 | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100908082; called by muse, mutect2, varscan2
- CAMTA2 | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100772617; called by muse, mutect2, varscan2
- CCDC22 | c.1690C>T p.H564Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873164; called by muse, mutect2, varscan2
- CCDC9B | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs1256386658, COSV101233520; called by muse, mutect2, varscan2
- CHI3L2 | c.771G>T p.M257I | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV100869288; called by muse, mutect2, varscan2
- CIAO3 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as rs201488709, COSV99284858; called by muse, mutect2, varscan2
- CPSF7 | c.1154A>G p.N385S (on ENST00000394888 / NM_001136040.4; = p.N428S on NM_024811.4) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.035); catalogued as rs1054948343, COSV100467333; called by muse, mutect2, varscan2
- DNAH8 | c.8884C>G p.R2962G | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100543317, COSV59421538, COSV59422300; called by muse, mutect2, varscan2
- EIF3A | c.2462A>G p.Q821R | Missense Mutation (SNP) | VAF 111/137 reads (81%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100974621; called by muse, mutect2, varscan2
- GLUD2 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs201021827, COSV60152595; called by muse, mutect2, varscan2
- GRIK3 | c.2500C>G p.L834V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.638); catalogued as rs200839937, COSV66141511; called by muse, mutect2, varscan2
- IGHV3-38 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs369602723; called by muse, mutect2, varscan2
- JAG2 | c.3179C>G p.S1060* | Nonsense Mutation (SNP) | VAF 51/111 reads (46%) | catalogued as COSV100078415, COSV59306065; called by muse, mutect2, varscan2
- KATNIP | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs376515834; called by muse, mutect2, varscan2
- LRP1 | c.8365C>T p.P2789S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as COSV99675890; called by muse, mutect2, varscan2
- MPP2 | c.1375C>T p.R459W (on ENST00000461854 / NM_001278372.2; = p.R435W on NM_005374.5) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as rs776118266, COSV52236622; called by muse, mutect2, varscan2
- PPFIA3 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100494931; called by muse, mutect2, varscan2
- PRKCI | c.1530A>T p.Q510H | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99855888; called by muse, mutect2, varscan2
- PSG11 | c.587C>A p.S196Y | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV100105819; called by muse, mutect2, varscan2
- RAB41 | c.106T>C p.F36L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.567); catalogued as COSV99333679; called by muse, mutect2, varscan2
- RGS9 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1453211373, COSV99287492; called by muse, mutect2, varscan2
- RIPK4 | c.1357G>A p.V453I (on ENST00000352483; = p.V405I on NM_020639.3) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201375165, COSV100204964; called by muse, mutect2, varscan2
- SLC28A1 | c.1807C>A p.L603I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.06); catalogued as COSV99722980; called by muse, mutect2, varscan2
- SLC35F1 | c.403T>A p.L135M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as COSV100837749; called by muse, mutect2, varscan2
- SLC9A3 | c.1045A>C p.I349L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV99376121; called by muse, mutect2, varscan2
- TLR1 | c.1297A>G p.N433D | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100458517; called by muse, mutect2, varscan2
- WWC1 | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs771279028, COSV54660989; called by muse, mutect2, varscan2
- XK | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV66120600; called by muse, mutect2, varscan2
- ZC3H18 | c.198C>G p.H66Q | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV99964124; called by muse, mutect2, varscan2
- DAZAP1 | c.922_924delinsA p.G308Sfs*118 | Frame Shift Del (DEL) | VAF 25/29 reads (86%) | called by pindel, varscan2*
- NFE2L1 | c.1501_1510del p.S501Lfs*51 | Frame Shift Del (DEL) | VAF 25/55 reads (45%) | called by mutect2, pindel, varscan2
- SCAF11 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2
- ELOVL4 | c.228T>A p.R76= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100876274; called by muse, mutect2, varscan2
- OR52L1 | c.486C>T p.I162= | Silent (SNP) | VAF 37/41 reads (90%) | catalogued as rs776523694, COSV59986837, COSV59989188; called by muse, mutect2, varscan2
- PCDHGA10 | c.1593G>A p.E531= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV99538629; called by muse, mutect2, varscan2
- PRL | c.459G>T p.R153= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV100123031; called by muse, mutect2, varscan2
- SLC24A1 | c.1695C>T p.Y565= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV99978295; called by muse, mutect2, varscan2
- SOX30 | c.2261A>G p.*754= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV99398453; called by muse, mutect2, varscan2
- TEX44 | c.1104C>T p.T368= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as rs760869633, COSV100009738; called by muse, mutect2, varscan2
- TTC6 | c.117C>T p.N39= (on ENST00000267368; = p.N1308= on NM_001310135.3) | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as COSV99941880; called by muse, mutect2, varscan2
- MTSS1 | c.1036-933G>A | Intron (SNP) | VAF 19/51 reads (37%) | catalogued as rs768419427, COSV100274905; called by muse, mutect2, varscan2
